Somatic mutation profile of tumor specimen 0DKRD3 from CCDI case PBBYMD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 16.0 years (5,854 days).
Specimen 0DKRD3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29098daa-47e1-4acb-89e3-fd87a2d11d2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKRCE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74730e01-686c-4884-ada4-776b32079657

The open-access MAF lists 40 somatic variants for this specimen: 30 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Intron 5, Silent 4, Nonsense Mutation 4, 3'UTR 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.615_618del p.K206Pfs*15 | Frame Shift Del (DEL) | VAF 353/1138 reads (31%) | catalogued as rs1555534147; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 371/697 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2407C>T p.Q803* | Nonsense Mutation (SNP) | VAF 45/1344 reads (3%) | catalogued as COSV55001391; called by muse, mutect2
- ADAP1 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 57/1088 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs567958546; called by muse, mutect2
- ADGRL2 | c.1372A>G p.I458V | Missense Mutation (SNP) | VAF 105/527 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs199620944; called by muse, mutect2, varscan2
- CCDC88C | c.4414G>A p.D1472N | Missense Mutation (SNP) | VAF 166/765 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs758183068; called by muse, mutect2, varscan2
- DPP10 | c.2087C>T p.S696F | Missense Mutation (SNP) | VAF 40/988 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV100067130; called by muse, mutect2
- H3-5 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 378/1247 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs144139961; called by muse, varscan2
- MXRA5 | c.7596G>T p.Q2532H | Missense Mutation (SNP) | VAF 51/66 reads (77%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.698); catalogued as COSV54238438; called by muse, mutect2, varscan2
- NUP160 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 151/614 reads (25%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs1200763037; called by muse, mutect2, varscan2
- ODF3B | c.143C>A p.A48D | Missense Mutation (SNP) | VAF 158/1041 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.66); catalogued as rs1042215932; called by muse, mutect2, varscan2
- OR2A2 | c.254T>C p.M85T | Missense Mutation (SNP) | VAF 119/799 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs574785094, COSV68872581; called by muse, mutect2, varscan2
- SFMBT2 | c.2249C>T p.A750V | Missense Mutation (SNP) | VAF 314/862 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs375469710; called by muse, mutect2, varscan2
- SH3BP4 | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 210/828 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs996292773, COSV100749325; called by muse, mutect2, varscan2
- ZNF777 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 150/888 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs201502980, COSV56099608; called by muse, mutect2, varscan2
- ADD3 | c.1234G>T p.A412S | Missense Mutation (SNP) | VAF 269/760 reads (35%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.952); called by mutect2, varscan2
- CACNB3 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 214/635 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CCDC88C | c.4203-1G>A p.X1401_splice | Splice Site (SNP) | VAF 176/470 reads (37%) | called by muse, mutect2, varscan2
- CRYBA1 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 159/637 reads (25%) | called by muse, mutect2, varscan2
- ELF2 | c.1253C>T p.P418L (on ENST00000379550 / NM_001331036.2; = p.P358L on NM_006874.4) | Missense Mutation (SNP) | VAF 155/676 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EYS | c.3515A>T p.H1172L | Missense Mutation (SNP) | VAF 51/685 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2
- FAM193A | c.2912G>A p.G971D | Missense Mutation (SNP) | VAF 109/611 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- IYD | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 630/1005 reads (63%) | called by muse, mutect2, varscan2
- MYBPC1 | c.718C>T p.R240* (on ENST00000550270 / NM_206820.2; = p.R265* on NM_002465.4) | Nonsense Mutation (SNP) | VAF 151/1046 reads (14%) | called by muse, mutect2, varscan2
- OR4F21 | c.365G>C p.R122T | Missense Mutation (SNP) | VAF 167/1694 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OR4F21 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); called by mutect2, varscan2
- SLC23A1 | c.520G>T p.G174W | Missense Mutation (SNP) | VAF 146/618 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCA4 | c.3912G>C p.Q1304H | Missense Mutation (SNP) | VAF 34/933 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- SOAT2 | c.726A>C p.K242N | Missense Mutation (SNP) | VAF 76/487 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP2 | c.65A>G p.Y22C | Missense Mutation (SNP) | VAF 61/660 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.65); called by muse, mutect2
- CNGA3 | c.1725C>T p.D575= | Silent (SNP) | VAF 171/1263 reads (14%) | catalogued as rs148867596; called by muse, mutect2, varscan2
- PCLO | c.759T>C p.G253= | Silent (SNP) | VAF 231/718 reads (32%) | called by muse, mutect2, varscan2
- S1PR1 | c.103C>T p.L35= | Silent (SNP) | VAF 392/759 reads (52%) | called by muse, mutect2, varscan2
- UNC13B | c.2313C>T p.D771= | Silent (SNP) | VAF 145/621 reads (23%) | catalogued as rs199752726; called by muse, mutect2, varscan2
- AC024598.1 | c.1130-853T>C | Intron (SNP) | VAF 114/760 reads (15%) | called by muse, mutect2, varscan2
- ACE | c.3692-45G>T | Intron (SNP) | VAF 20/362 reads (6%) | called by muse, mutect2
- C2orf72 | c.*56G>A | 3'UTR (SNP) | VAF 107/812 reads (13%) | catalogued as rs546520299; called by muse, mutect2, varscan2
- DYSF | c.2926-21C>A | Intron (SNP) | VAF 104/1177 reads (9%) | called by muse, mutect2
- HNF1A | c.1309+76C>T | Intron (SNP) | VAF 32/486 reads (7%) | called by muse, mutect2
- YTHDF3 | c.49+30C>T | Intron (SNP) | VAF 95/966 reads (10%) | catalogued as rs1183785798; called by muse, mutect2, varscan2
